Somatic mutation profile of tumor specimen BA2199D (aliquot aq-BA2199D) from BEATAML1.0 case 2317, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 34.8 years (12,715 days).
Specimen BA2199D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 913d563f-8998-4755-9b60-519c26bf35f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2599D (Solid Tissue Normal), aliquot aq-BA2599D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a362586-7218-421c-a996-2aa61a995e16

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- JAK3 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV71685795; called by muse, mutect2, varscan2
- MIP | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV57788807, COSV99234471; called by muse, mutect2
- VILL | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs372105661; called by muse, varscan2
- SYDE2 | c.3400G>A p.V1134I | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- TAF6L | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- KDM6B | c.4908+38C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
